Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90V, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A90V-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

"Right testis":

- Classic seminoma.
- Greatest dimension of neoplasia: 6.5cm.
- Angiolymphatic invasion: present.
- Perineural invasion: not detected.
- Tunica albuginea: uninvolved by neoplasia.
- Tunica vaginalis: uninvolved by neoplasia.
- Epididymis: uninvolved by neoplasia.
- Spermatic cord: uninvolved by neoplasia.
- Surgical margin (spermatic cord): uninvolved by neoplasia.

ICDO-3

Seminoma NOS 9061/3
Site R Testis NOS C62.9
JW 3/13/14

Reviewed by: MM	Reviewed: 11/5/13	

Source: NCI Genomic Data Commons file 8c129efd-3f1d-4b69-8fb8-b34210109010 (TCGA-YU-A90V-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).